Somatic mutation profile of tumor specimen RC-B54G-TTP1-A (aliquot RC-B54G-TTP1-A-1-1-D-A93N-47) from RC case RC-B54G, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, ALK negative; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 27.1 years (9,895 days).
Specimen RC-B54G-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f91eb771-1683-42e0-8618-c53415e96f71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B54G-NM1-B (Bone Marrow Components NOS; tissue type Normal), aliquot RC-B54G-NM1-B-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386481bb-83c7-40b4-9584-9bff6600b715

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTHRC1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs145881116; called by muse, mutect2
- POTEJ | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758115264; called by muse, mutect2, varscan2
- EMB | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- SNX29 | c.2036A>G p.Q679R | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- MAP4 | c.1999+4631G>C | Intron (SNP) | VAF 19/223 reads (9%) | called by muse, mutect2
- PML | c.1710+694C>T | Intron (SNP) | VAF 40/527 reads (8%) | catalogued as rs374669015; called by muse, mutect2
